Somatic mutation profile of tumor specimen TCGA-CW-5585-01A (aliquot TCGA-CW-5585-01A-01D-1534-10) from TCGA case TCGA-CW-5585, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 51.7 years (18,898 days).
Specimen TCGA-CW-5585-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09b78bfc-7642-4b21-a27e-b646a49f73d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5585-11A (Solid Tissue Normal), aliquot TCGA-CW-5585-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b8af15f-5a7e-4fce-a659-38fcc10cf7ff

The open-access MAF lists 47 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 30, Silent 7, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5383A>T p.N1795Y (on ENST00000272895 / NM_173076.3; = p.N1477Y on NM_015657.3) | Missense Mutation (SNP) | VAF 152/431 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55959338; called by muse, mutect2, varscan2
- ABCA13 | c.3347A>G p.E1116G | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV70028684; called by muse, mutect2, varscan2
- APPL1 | c.1247+2T>A p.X416_splice | Splice Site (SNP) | VAF 58/159 reads (36%) | catalogued as rs1471402914, COSV55700849; called by muse, mutect2, varscan2
- ARHGEF7 | c.2446G>A p.E816K (on ENST00000646102 / NM_001354046.1; = p.E600K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 285/760 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV54543264; called by muse, mutect2, varscan2
- BRD7 | c.1340A>G p.E447G | Missense Mutation (SNP) | VAF 107/272 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV67158796; called by muse, mutect2, varscan2
- CPB1 | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 234/603 reads (39%) | catalogued as COSV51573436; called by muse, mutect2, varscan2
- DCHS1 | c.3886C>A p.Q1296K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.239); catalogued as COSV55035555; called by muse, mutect2, varscan2
- ECPAS | c.4844T>A p.L1615Q | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52197085; called by muse, mutect2, varscan2
- FADS2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as rs140356378, COSV99608607; called by muse, mutect2, varscan2
- GEMIN4 | c.1895T>A p.M632K | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV56745897; called by muse, mutect2, varscan2
- KLHL24 | c.1563A>C p.E521D | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV54426170; called by muse, mutect2
- MAGEE2 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 110/152 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1431475863, COSV64897712; called by muse, mutect2, varscan2
- MINDY2 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 185/320 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs757892501, COSV57506115; called by muse, mutect2, varscan2
- ODF2 | c.1835A>G p.E612G (on ENST00000434106 / NM_153433.2; = p.E588G on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV63547003, COSV63547017; called by muse, mutect2, varscan2
- PALB2 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 20/648 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55165187; called by muse, mutect2
- PDGFRA | c.3078C>A p.D1026E | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV57267994; called by muse, mutect2, varscan2
- PDSS1 | c.261C>A p.H87Q | Missense Mutation (SNP) | VAF 124/390 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV66059060; called by muse, mutect2, varscan2
- POLR2B | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 172/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58900415; called by muse, mutect2, varscan2
- PRPS1L1 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.079); catalogued as COSV72649894; called by muse, mutect2, varscan2
- PRUNE2 | c.7765A>G p.T2589A | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.444); catalogued as COSV65041530; called by muse, mutect2, varscan2
- RBM43 | c.913_916del p.E305Kfs*3 | Frame Shift Del (DEL) | VAF 184/513 reads (36%) | catalogued as rs773044666; called by mutect2, pindel, varscan2
- RTN2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55594069; called by muse, mutect2, varscan2
- SCN3A | c.5716A>G p.I1906V | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV51809821; called by muse, mutect2
- SLC12A5 | c.128G>A p.G43D (on ENST00000454036 / NM_001134771.2; = p.G20D on NM_020708.5) | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1156589458, COSV54793638; called by muse, mutect2, varscan2
- SLC27A5 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as COSV54019606; called by muse, mutect2, varscan2
- SLC28A2 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61664055; called by muse, mutect2, varscan2
- SVEP1 | c.8002C>G p.P2668A | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52839220; called by muse, mutect2, varscan2
- TPI1 | c.256A>G p.I86V (on ENST00000229270; = p.I49V on NM_000365.6) | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV51290172; called by muse, mutect2, varscan2
- TRPM7 | c.3005A>G p.Y1002C | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs745515969, COSV57916364; called by muse, mutect2, varscan2
- UBA5 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV53904758; called by muse, mutect2
- UBXN11 | c.1292+2T>G p.X431_splice (on ENST00000374221 / NM_183008.2; = p.X398_splice on NM_145345.2) | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as COSV53329340; called by muse, mutect2, varscan2
- UMODL1 | c.2329G>T p.E777* (on ENST00000408910 / NM_001004416.2; = p.E905* on NM_173568.3) | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV68573530; called by muse, mutect2, varscan2
- WARS2 | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52478406; called by muse, mutect2, varscan2
- ZNF512B | c.1199A>G p.E400G | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV53870629; called by muse, varscan2
- AFF3 | c.848del p.K283Sfs*23 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- CEP290 | c.1400del p.N467Ifs*8 | Frame Shift Del (DEL) | VAF 251/807 reads (31%) | called by mutect2, pindel, varscan2
- CERS4 | c.768_770del p.Q256_Y257delinsH | In Frame Del (DEL) | VAF 131/394 reads (33%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by muse, mutect2
- SOCS4 | c.1233dup p.P412Sfs*14 | Frame Shift Ins (INS) | VAF 91/278 reads (33%) | called by mutect2, pindel, varscan2
- THBS3 | c.1863_1864del p.C621* | Nonsense Mutation (DEL) | VAF 54/190 reads (28%) | called by pindel, varscan2
- FBN3 | c.1947C>T p.H649= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs773667851, COSV54460522; called by muse, mutect2, varscan2
- NXPH4 | c.816G>A p.K272= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV61073986; called by muse, mutect2, varscan2
- OSBPL6 | c.2319T>G p.S773= | Silent (SNP) | VAF 228/701 reads (33%) | catalogued as COSV51917822; called by muse, mutect2, varscan2
- TAF1C | c.744C>A p.T248= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58986357; called by muse, mutect2, varscan2
- USP34 | c.1962C>T p.C654= | Silent (SNP) | VAF 84/194 reads (43%) | catalogued as COSV68401302; called by muse, mutect2, varscan2
- VCAN | c.5433T>C p.S1811= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV54105072; called by muse, mutect2, varscan2
- ZNF783 | c.336G>T p.R112= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV65185435; called by muse, mutect2, varscan2
